Somatic mutation profile of tumor specimen TCGA-AA-3968-01A (aliquot TCGA-AA-3968-01A-01W-0995-10) from TCGA case TCGA-AA-3968, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 55.0 years (20,089 days).
Specimen TCGA-AA-3968-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bca44663-0e48-46d1-9084-e75b520bad73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3968-10A (Blood Derived Normal), aliquot TCGA-AA-3968-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23f6b551-1c4a-4742-98e1-744e1359a672

The open-access MAF lists 131 somatic variants for this specimen: 107 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 20, Nonsense Mutation 9, Splice Site 8, Frame Shift Ins 2, RNA 2, Splice Region 1, Intron 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as rs72559722, CM001605, COSV56849386; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 69/83 reads (83%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADCY2 | c.2662G>A p.V888I | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57869521; called by muse, mutect2, varscan2
- APC | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as CM105842, COSV57327519; called by muse, mutect2, varscan2
- APC | c.4316del p.P1439Lfs*34 | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | catalogued as COSV57382727; called by mutect2, pindel, varscan2
- BCO1 | c.1207+1G>C p.X403_splice | Splice Site (SNP) | VAF 20/76 reads (26%) | catalogued as rs1024064559, COSV99258789; called by muse, mutect2, varscan2
- BMP10 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs141935259; called by muse, mutect2, varscan2
- C2CD2 | c.1971G>T p.E657D | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV100298477; called by muse, mutect2
- CD69 | c.130G>C p.A44P | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99946216; called by muse, mutect2, varscan2
- CDK6 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 112/263 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV99721800; called by muse, mutect2, varscan2
- CFAP94 | c.1465C>T p.P489S (on ENST00000320267 / NM_001352064.2; = p.P495S on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/272 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); catalogued as COSV100209808; called by muse, mutect2
- COL11A1 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.011); catalogued as COSV62200699; called by muse, mutect2, varscan2
- COL4A4 | c.2752G>A p.G918R | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372606845, CM148122, COSV61630020; called by muse, mutect2, varscan2
- CORIN | c.1843+1G>T p.X615_splice | Splice Site (SNP) | VAF 12/99 reads (12%) | catalogued as COSV99902950, COSV99904611; called by muse, mutect2, varscan2
- CORIN | c.211A>G p.T71A | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.024); catalogued as COSV99904613; called by muse, mutect2
- CPS1 | c.2308G>A p.V770I | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs1237628982, COSV99244361; called by muse, mutect2, varscan2
- CSMD3 | c.7733G>A p.G2578E (on ENST00000297405 / NM_001363185.1; = p.G2474E on NM_052900.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52177476; called by muse, mutect2, varscan2
- CYP4V2 | c.1225+2T>A p.X409_splice | Splice Site (SNP) | VAF 481/1348 reads (36%) | catalogued as COSV101115001; called by muse, mutect2, varscan2
- CYTIP | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.018); catalogued as rs1168235702, COSV99938616; called by muse, mutect2
- DHX37 | c.2956G>A p.V986M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs111456585, COSV58135296; called by muse, mutect2, varscan2
- DNAH17 | c.8206G>T p.A2736S | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV67762228; called by muse, mutect2, varscan2
- DOCK4 | c.4868G>T p.G1623V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1262712751, COSV101448022; called by muse, mutect2, varscan2
- EFCAB5 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100300907; called by muse, mutect2, varscan2
- ESS2 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs754954476, COSV99351310; called by muse, mutect2
- EXOSC10 | c.1999G>T p.E667* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100442974; called by muse, mutect2, varscan2
- FAU | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs767227130, COSV54196154; called by muse, mutect2, varscan2
- G6PD | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as COSV100855161; called by muse, mutect2, varscan2
- GALNT17 | c.1362C>A p.Y454* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | catalogued as COSV100356605; called by muse, mutect2, varscan2
- GJA1 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs763503078, COSV56996801; called by muse, mutect2, varscan2
- GP2 | c.725T>C p.L242S (on ENST00000381362 / NM_001007240.3; = p.L239S on NM_001502.4) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.686); catalogued as COSV100221689; called by muse, mutect2, varscan2
- GPC4 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100895620; called by muse, mutect2, varscan2
- GPN1 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53118064; called by muse, mutect2, varscan2
- GPR50 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 81/245 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs370344133, COSV54440264; called by muse, mutect2, varscan2
- GSPT2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV100468435; called by muse, mutect2, varscan2
- GSPT2 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.193); catalogued as rs141788007, COSV61215381; called by muse, mutect2, varscan2
- HDX | c.1118T>C p.L373S | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV99948167; called by muse, mutect2, varscan2
- HMG20A | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as rs1392475263, COSV60312883, COSV60313111; called by muse, mutect2, varscan2
- IL18RAP | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV51825660; called by mutect2, varscan2
- IQGAP3 | c.542A>G p.K181R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100752447; called by muse, mutect2
- ITPR2 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99659678; called by muse, mutect2
- KANK1 | c.3971T>C p.V1324A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs1289544487, COSV66529332; called by muse, mutect2, varscan2
- KCNAB3 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs142341353; called by muse, mutect2, varscan2
- KLHL32 | c.820C>G p.Q274E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV100987521; called by muse, mutect2, varscan2
- KLHL4 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100910241; called by muse, mutect2, varscan2
- KRT15 | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99563335; called by muse, mutect2, varscan2
- LAMB4 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as rs189715083, COSV52720629; called by muse, mutect2, varscan2
- LDLRAD2 | c.83C>A p.T28K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as COSV100760969; called by muse, mutect2, varscan2
- LHX8 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.046); catalogued as COSV53954262; called by muse, mutect2, varscan2
- LIPI | c.915C>A p.S305R | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100754054; called by muse, mutect2, varscan2
- LRRC31 | c.1084C>T p.L362F | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99247182; called by muse, mutect2, varscan2
- MATR3 | c.2248A>G p.N750D | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100735345; called by muse, mutect2
- MDGA1 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 34/123 reads (28%) | catalogued as rs1449487161, COSV99776398; called by muse, mutect2, varscan2
- MIA3 | c.3916G>A p.E1306K | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV100485265; called by muse, mutect2, varscan2
- MMD2 | c.543C>A p.Y181* (on ENST00000404774 / NM_001100600.2; = p.Y157* on NM_198403.4) | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs771413791, COSV101287191; called by muse, varscan2
- MYH6 | c.313C>A p.L105I | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs750029272, COSV62449962, COSV62454420; called by muse, mutect2, varscan2
- NF2 | c.599+1G>C p.X200_splice | Splice Site (SNP) | VAF 130/357 reads (36%) | catalogued as CS951487, COSV100099758, COSV104404753, COSV58527473; called by muse, mutect2, varscan2
- NLN | c.1504G>A p.V502M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772545743, COSV101114524; called by muse, varscan2
- NPY5R | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as COSV100642977; called by muse, mutect2, varscan2
- NSD1 | c.1742A>G p.E581G | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV100729901; called by muse, mutect2, varscan2
- NUP160 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 12/278 reads (4%) | catalogued as COSV101021557; called by muse, mutect2
- OR4A15 | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.014); catalogued as rs147950388; called by muse, mutect2, varscan2
- OR5B2 | c.300C>A p.F100L | Missense Mutation (SNP) | VAF 5/135 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV100223012; called by muse, mutect2
- OR5H2 | c.199T>C p.F67L | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV62352090; called by muse, mutect2, varscan2
- OR5L2 | c.514A>T p.N172Y | Missense Mutation (SNP) | VAF 111/541 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101004442; called by muse, mutect2, varscan2
- P2RY4 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.241); catalogued as COSV100997060; called by muse, mutect2, varscan2
- PAPPA2 | c.29G>T p.S10I | Missense Mutation (SNP) | VAF 55/233 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.121); catalogued as COSV62788164; called by muse, mutect2, varscan2
- PCDH10 | c.237A>G p.I79M | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99994702; called by muse, mutect2, varscan2
- PCDH15 | c.4589A>C p.K1530T (on ENST00000617271 / NM_001142770.3; = p.E1518D on NM_001142769.3) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | PolyPhen possibly damaging (0.702); catalogued as rs1413409135, COSV100905907; called by muse, varscan2
- POM121L12 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68693109; called by muse, mutect2, varscan2
- PRDM1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 81/429 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64844667; called by muse, mutect2, varscan2
- PTPRH | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99671534; called by muse, mutect2
- RAB17 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs761536358, COSV52815869; called by muse, mutect2, varscan2
- RAD21 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); catalogued as COSV52063122; called by muse, mutect2
- RYR2 | c.10811G>A p.R3604Q | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs56228594, COSV63692889, COSV63714903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.2458C>T p.R820W | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs759323106, COSV67379581; called by muse, mutect2, varscan2
- SEPTIN1 | c.257C>G p.S86C (on ENST00000321367; = p.S39C on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100363182; called by muse, mutect2
- SH3D21 | c.1111G>A p.A371T (on ENST00000453908 / NM_001162530.2; = p.A260T on NM_024676.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs369876264, COSV99584278; called by mutect2, varscan2
- SMU1 | c.1122+2T>G p.X374_splice | Splice Site (SNP) | VAF 20/116 reads (17%) | catalogued as COSV101238600; called by mutect2, varscan2
- SNX19 | c.1654T>C p.Y552H | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99773704; called by muse, mutect2, varscan2
- SPEM1 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.117); catalogued as rs768831098, COSV57210134; called by muse, mutect2, varscan2
- STON1 | c.2114G>A p.R705Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as COSV100562342; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2401A>T p.T801S | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.138); catalogued as COSV100562343; called by muse, mutect2, varscan2
- SULT1C2 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as rs1274831635, COSV52267606; called by muse, mutect2, varscan2
- TARS2 | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100946137; called by muse, mutect2, varscan2
- TDRD3 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99541336; called by muse, mutect2
- TDRD5 | c.1521G>T p.R507= | Splice Region (SNP) | VAF 99/216 reads (46%) | catalogued as COSV99677431; called by muse, mutect2, varscan2
- TENM3 | c.53A>G p.E18G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.078); catalogued as COSV101305532; called by muse, mutect2, varscan2
- THOC2 | c.3026C>A p.P1009Q | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99834377; called by muse, mutect2
- TMEM220 | c.93G>C p.E31D | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.167); catalogued as COSV100541460; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4988G>A p.R1663Q | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369411354; called by muse, mutect2, varscan2
- TOX | c.936G>T p.K312N | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100813151; called by muse, mutect2, varscan2
- TRIM49 | c.185T>C p.I62T | Missense Mutation (SNP) | VAF 55/404 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV61672177; called by muse, mutect2, varscan2
- TTN | c.90382G>A p.V30128I (on ENST00000591111; = p.V22704I on NM_003319.4) | Missense Mutation (SNP) | VAF 30/151 reads (20%) | PolyPhen benign (0.431); catalogued as rs374445709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGGT1 | c.3453+1G>T p.X1151_splice | Splice Site (SNP) | VAF 38/122 reads (31%) | catalogued as COSV99391305; called by muse, mutect2, varscan2
- VPS29 | c.71A>C p.K24T | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV100804922; called by muse, mutect2, varscan2
- VRK1 | c.1068+1G>C p.X356_splice | Splice Site (SNP) | VAF 22/85 reads (26%) | catalogued as COSV99388705; called by muse, mutect2, varscan2
- WARS2 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1300524106, COSV52478833; called by muse, mutect2, varscan2
- ZFHX4 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs1479366382, COSV50479193; called by muse, mutect2, varscan2
- ZNF510 | c.1304G>C p.S435T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as COSV99793983; called by muse, mutect2, varscan2
- ZNF610 | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV100017073; called by muse, mutect2, varscan2
- ZNF652 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as rs770946812, COSV100755722; called by muse, mutect2, varscan2
- ZNF718 | c.1212T>G p.F404L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374195019; called by muse, mutect2, varscan2
- ZSCAN20 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100792765; called by muse, mutect2, varscan2
- ARHGAP30 | c.3210dup p.R1071Qfs*7 (on ENST00000368013 / NM_001025598.2; = p.R860Qfs*7 on NM_181720.3) | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- CALD1 | c.1380dup p.E461Rfs*6 | Frame Shift Ins (INS) | VAF 15/102 reads (15%) | called by mutect2, pindel, varscan2
- ENAM | c.1537A>G p.S513G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.611); called by muse, mutect2
- R3HDM1 | c.698+3_698+6del p.X233_splice | Splice Site (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- AOC3 | c.2160C>T p.A720= | Silent (SNP) | VAF 209/262 reads (80%) | catalogued as rs753309316, COSV100396356; called by muse, mutect2, varscan2
- CENPA | c.127C>A p.R43= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV51982395, COSV99273296; called by muse, mutect2
- CHST2 | c.813C>T p.V271= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs1472951532, COSV58887349; called by muse, mutect2, varscan2
- COL4A1 | c.1656C>T p.P552= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as rs576690537, COSV101011004, COSV101011633; called by muse, mutect2, varscan2
- COL5A1 | c.3303C>T p.I1101= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs760754491, COSV100880669; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- DBN1 | c.1341C>T p.H447= | Silent (SNP) | VAF 4/6 reads (67%) | catalogued as rs766622471, COSV52787440; called by mutect2, varscan2
- DCDC1 | c.657C>T p.D219= | Silent (SNP) | VAF 43/67 reads (64%) | catalogued as rs147472755; called by muse, mutect2, varscan2
- DHX36 | c.1797A>G p.R599= | Silent (SNP) | VAF 43/186 reads (23%) | catalogued as COSV100274022; called by muse, mutect2, varscan2
- DMRT2 | c.561C>T p.F187= | Silent (SNP) | VAF 63/111 reads (57%) | catalogued as COSV52400721; called by muse, mutect2, varscan2
- GRM4 | c.2298G>A p.T766= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs1469541415, COSV65213132; called by muse, mutect2, varscan2
- LZTS1 | c.300G>A p.P100= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs368947201; called by muse, mutect2, varscan2
- MFAP3L | c.912C>T p.D304= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs377059924, COSV64371970; called by muse, mutect2, varscan2
- POGLUT2 | c.882G>A p.T294= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs1267596670, COSV65682740; called by muse, mutect2, varscan2
- SCN5A | c.864C>T p.N288= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs373728726; ClinVar: likely benign; called by mutect2, varscan2
- SLC19A2 | c.549A>T p.A183= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99357198; called by muse, mutect2, varscan2
- SLC6A9 | c.1899C>T p.C633= (on ENST00000360584 / NM_201649.4; = p.C579= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV100746576; called by muse, mutect2, varscan2
- SSTR4 | c.483C>T p.S161= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1340296838, COSV99658852; called by muse, mutect2, varscan2
- TEX15 | c.3192G>A p.S1064= (on ENST00000256246; = p.S1447= on NM_001350162.2) | Silent (SNP) | VAF 62/118 reads (53%) | catalogued as rs779449393, COSV99822303; called by muse, mutect2, varscan2
- WAC | c.144C>T p.D48= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs1191133532, COSV61570256; called by muse, mutect2, varscan2
- ZNF674 | c.12C>T p.S4= | Silent (SNP) | VAF 9/218 reads (4%) | catalogued as COSV101345070; called by muse, mutect2
- CCSER1 | c.2094+23125G>A | Intron (SNP) | VAF 10/26 reads (38%) | catalogued as rs752050431, COSV61475582; called by muse, mutect2, varscan2
- MCF2 | chrX:139646824 T>C | 5'Flank (SNP) | VAF 36/362 reads (10%) | catalogued as COSV100645246; called by muse, mutect2
- MIR503 | n.31A>G | RNA (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- MIR503 | n.30G>A | RNA (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
